Somatic mutation profile of tumor specimen TCGA-DU-5872-02A (aliquot TCGA-DU-5872-02A-21D-A36O-08) from TCGA case TCGA-DU-5872, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Brain, NOS; Tumor grade: G2; Age at diagnosis: 43.8 years (15,986 days).
Specimen TCGA-DU-5872-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 69bf0b76-a986-4ec8-9af2-859f931c0cb4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-5872-10A (Blood Derived Normal), aliquot TCGA-DU-5872-10A-01D-1705-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/265dcfd2-cb99-4c41-bfae-d55c577a786a

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Nonsense Mutation 1, Silent 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 7/71 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by mutect2, varscan2
- BUB1 | c.895A>G p.K299E | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.039); catalogued as COSV57063324; called by muse, mutect2
- LAMA3 | c.3717T>G p.L1239= | Splice Region (SNP) | VAF 6/62 reads (10%) | catalogued as COSV58068069; called by muse, mutect2
- TAS1R2 | c.1793C>A p.S598* | Nonsense Mutation (SNP) | VAF 6/61 reads (10%) | catalogued as COSV100946207, COSV64744810; called by muse, mutect2, varscan2
- PSMD12 | c.852A>T p.S284= | Silent (SNP) | VAF 15/117 reads (13%) | catalogued as COSV62065628; called by muse, mutect2, varscan2
